FM case AD15712 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/f24dcc91-ae7f-476d-a49d-591cce06585a

Female, 45.2 years: Mucinous carcinoma (ICD-O-3 8480/3) of the appendix; primary biopsied or resected from the appendix. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
